MMRF case MMRF_1720 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c62170e0-7a82-4e36-b384-6fc0e7a18cfe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Dead; Days to death: 64 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.5 years (30,515 days); ISS stage: III; Days to last known disease status: 64 days; Days to last follow up: 64 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 38 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 38 days.

Follow-up (2 entries)
- Days to follow up: 1 day; ECOG performance status: 2.
- Follow-up contact recording only the day: day 64.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2 mmol/L.
- Total Protein 6 g/dL.
- Beta 2 Microglobulin 21.1 µg/mL.
- Glucose 6.33 mmol/L.
- Creatinine 237 µmol/L.
- M Protein 1.8 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 277 mg/dL.
- Albumin 22 g/L.
- Platelets 232 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL.
- Blood Urea Nitrogen 41.4 mmol/L.
- Hemoglobin 4.28 mmol/L.
- Immunoglobulin M 0.25 g/L.
- Leukocytes 7.2 ×10⁹/L.
- Immunoglobulin A 0.47 g/L.
- C-Reactive Protein 5.16 mg/dL.
- Absolute Neutrophil 6.4 ×10⁹/L.
- Immunoglobulin G 24.2 g/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1720_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1720_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
